Somatic mutation profile of tumor specimen TCGA-2Z-A9JJ-01A (aliquot TCGA-2Z-A9JJ-01A-11D-A42J-10) from TCGA case TCGA-2Z-A9JJ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 69.1 years (25,240 days).
Specimen TCGA-2Z-A9JJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb036116-9e33-4697-8957-8d84165cbca6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9JJ-10A (Blood Derived Normal), aliquot TCGA-2Z-A9JJ-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a821549-bca8-4dfe-a912-57de17b9a4f2

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 14, Silent 2, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.2198_2199insT p.E733Dfs*53 (on ENST00000404938 / NM_001163941.2; = p.E288Dfs*53 on NM_178559.6) | Frame Shift Ins (INS) | VAF 15/78 reads (19%) | catalogued as COSV99328905; called by mutect2, pindel, varscan2
- ADGRA2 | c.1282T>C p.Y428H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0.009); catalogued as COSV100178184; called by muse, mutect2, varscan2
- ALKBH8 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs755059121, COSV52833710; called by muse, mutect2, varscan2
- AP2A2 | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1190285921, COSV100173135; called by muse, mutect2
- CD300C | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.834); catalogued as COSV100423287; called by muse, mutect2, varscan2
- CELF3 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs1033271069, COSV99310455; called by muse, mutect2, varscan2
- CELSR3 | c.6406G>T p.G2136C | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV50891910, COSV99374171; called by muse, mutect2, varscan2
- DMD | c.9041T>G p.L3014R | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.708); catalogued as CD054319, COSV100628234; called by muse, mutect2, varscan2
- DNAH8 | c.6161T>C p.M2054T | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100546287; called by muse, mutect2, varscan2
- DST | c.17317A>G p.K5773E (on ENST00000361203 / NM_001374722.1; = p.K3470E on NM_015548.5) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55013637, COSV99758026; called by muse, mutect2, varscan2
- ITPR2 | c.2020C>T p.Q674* | Nonsense Mutation (SNP) | VAF 29/101 reads (29%) | catalogued as COSV101190069; called by muse, mutect2, varscan2
- PRDM15 | c.2783A>C p.Q928P | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); catalogued as COSV99520463; called by muse, mutect2, varscan2
- SPDEF | c.932A>G p.Q311R | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99763218; called by muse, mutect2, varscan2
- TIMP1 | c.458T>G p.F153C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); catalogued as COSV99512231; called by muse, mutect2, varscan2
- TUBB | c.887C>G p.A296G | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.284); catalogued as rs1312842009, COSV100013412; called by muse, mutect2, varscan2
- VPS13A | c.5573A>G p.K1858R | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV100653096; called by muse, mutect2, varscan2
- DPP4 | c.1181_1211del p.C394Sfs*4 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel
- MUC16 | c.24549C>T p.I8183= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV101200467; called by muse, mutect2, varscan2
- SPG11 | c.180G>A p.A60= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as rs765387108, COSV99969082; ClinVar: likely benign; called by muse, mutect2, varscan2
